Somatic mutation profile of tumor specimen TCGA-ER-A199-06A (aliquot TCGA-ER-A199-06A-11D-A197-08) from TCGA case TCGA-ER-A199, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.0 years (31,766 days).
Specimen TCGA-ER-A199-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff2001bb-b80b-4285-abaa-6275a9ca3226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A199-10A (Blood Derived Normal), aliquot TCGA-ER-A199-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5517f58-2017-4e53-9f95-53808164d8d8

The open-access MAF lists 314 somatic variants for this specimen: 214 protein-altering or splice-affecting, 92 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 92, Nonsense Mutation 8, RNA 6, Intron 2, Splice Region 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 39/154 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11336G>A p.G3779E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71285368; called by muse, mutect2
- ABCB1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947943; called by muse, mutect2, varscan2
- ABCC8 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs200687571, CM113479, CM118597, COSV56848525; called by muse, mutect2, varscan2
- ACSL6 | c.32G>A p.R11Q (on ENST00000379240; = p.R36Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs761782775, COSV57296607, COSV99734432; called by muse, mutect2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- ANKRD35 | c.1487G>A p.R496K | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV100841872, COSV62910024; called by muse, mutect2, varscan2
- AP2B1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51998361, COSV52003545; called by muse, mutect2, varscan2
- APH1A | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as COSV52528741; called by muse, mutect2, varscan2
- ARL9 | c.592C>T p.P198S (on ENST00000640821 / NM_001363794.2; = p.P56S on NM_206919.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs942334709, COSV63991133; called by muse, mutect2, varscan2
- ARR3 | c.130T>A p.L44I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as COSV57203813; called by muse, mutect2, varscan2
- ARSF | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63839303; called by muse, mutect2, varscan2
- ATP13A3 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1297241133, COSV55463127; called by muse, mutect2, varscan2
- ATP13A5 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60866921, COSV60867898; called by muse, mutect2, varscan2
- ATXN1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55213063; called by muse, mutect2, varscan2
- C6 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54708223; called by muse, mutect2, varscan2
- CAPN13 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54429696; called by muse, mutect2, varscan2
- CASKIN1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100623820; called by muse, mutect2, varscan2
- CBL | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs553979171, COSV50633292, COSV50643820; called by muse, mutect2, varscan2
- CCDC181 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs530288123, COSV63155897; called by muse, mutect2
- CCNB3 | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1246077293, COSV52071987; called by muse, mutect2, varscan2
- CD160 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV52522975; called by muse, mutect2, varscan2
- CD163L1 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.447); catalogued as COSV58013995; called by muse, mutect2, varscan2
- CD163L1 | c.1658G>A p.W553* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV58014005, COSV58017311; called by mutect2, varscan2
- CDH6 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs781442002, COSV54067394; called by muse, mutect2, varscan2
- CELA2A | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100657633, COSV62747368; called by muse, mutect2, varscan2
- CFAP70 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV60282281; called by muse, mutect2
- CFAP70 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868749938, COSV60282289; called by muse, mutect2, varscan2
- CHD4 | c.2513C>T p.S838F (on ENST00000357008 / NM_001363606.2; = p.S851F on NM_001273.5) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58898168; called by muse, mutect2, varscan2
- CHID1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262891751, COSV60258469; called by muse, mutect2
- CHIT1 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV55146256; called by muse, mutect2, varscan2
- CRISP1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV59993223; called by muse, mutect2, varscan2
- CRNN | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs531893930, COSV55121457; called by muse, mutect2, varscan2
- CTRC | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs142027137; called by muse, mutect2, varscan2
- CTSW | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV57172140; called by muse, mutect2, varscan2
- CUX1 | c.2974A>T p.T992S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52895691; called by muse, mutect2, varscan2
- CXCR3 | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65461780; called by muse, mutect2
- CYP2C18 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV53671181; called by muse, mutect2, varscan2
- CYP2U1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV60548639; called by muse, mutect2
- CYP4B1 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773046536, COSV54722739; called by muse, varscan2
- DAW1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as COSV59364624; called by muse, mutect2, varscan2
- DCAF6 | c.1604G>A p.S535N (on ENST00000312263 / NM_001349778.1; = p.S555N on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV56577177; called by muse, mutect2, varscan2
- DDX20 | c.2398C>T p.Q800* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as rs771793328, COSV63778452, COSV63778578; called by muse, mutect2, varscan2
- DLD | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs757220945, COSV52737454; called by muse, mutect2, varscan2
- DNAH11 | c.9662C>T p.A3221V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100177222; called by muse, mutect2, varscan2
- DNAH3 | c.6775G>A p.V2259M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.583); catalogued as rs1171335703, COSV54514215; called by muse, mutect2
- DNAH5 | c.13492G>A p.E4498K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54204981; called by muse, mutect2, varscan2
- DNAH8 | c.10253G>A p.R3418Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs866855066, COSV59436690; called by muse, mutect2, varscan2
- DNER | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59163454; called by muse, mutect2, varscan2
- DOCK11 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52236643; called by muse, mutect2, varscan2
- EDC4 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54645637; called by muse, mutect2
- EPHA3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60698692, COSV60722017; called by muse, mutect2, varscan2
- ESX1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV65424139; called by muse, mutect2, varscan2
- ETNK1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56884598; called by muse, mutect2, varscan2
- FAM83B | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs750088415, COSV60920984; called by muse, mutect2, varscan2
- FAM83D | c.1652G>A p.R551K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99464971; called by muse, mutect2, varscan2
- FBXL17 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100671269, COSV62851399; called by muse, mutect2
- FLNC | c.1435G>C p.A479P | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs772697482, COSV57953713; called by muse, mutect2, varscan2
- GALNT2 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779947137, COSV64194208; called by muse, mutect2, varscan2
- GBP3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52517987; called by muse, mutect2, varscan2
- GLYATL2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.645); catalogued as COSV54849551; called by muse, mutect2, varscan2
- GON4L | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs202156746, COSV55188745; called by muse, mutect2, varscan2
- GRIA1 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.015); catalogued as rs1425756849, COSV99598209, COSV99600376; called by muse, mutect2, varscan2
- GRIA2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV52386983; called by muse, mutect2, varscan2
- GRIA4 | c.849T>A p.D283E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as COSV56889513; called by muse, mutect2, varscan2
- GZMB | c.312C>G p.N104K | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV53540872; called by muse, mutect2, varscan2
- HAPLN1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV57146800; called by muse, mutect2
- HDHD2 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV56075676; called by muse, mutect2, varscan2
- HLA-E | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64927424; called by muse, mutect2, varscan2
- HM13 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV59436480; called by muse, mutect2, varscan2
- HPS3 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770402319, COSV56053614; called by muse, mutect2, varscan2
- HSPH1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60710925; called by muse, mutect2, varscan2
- IGDCC4 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61536182; called by muse, mutect2, varscan2
- IL1RL1 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV52114509, COSV52119594; called by muse, mutect2, varscan2
- IL6 | c.419C>G p.A140G | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV51732563; called by muse, mutect2, varscan2
- IL7R | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs756406426, COSV57405697; called by muse, mutect2, varscan2
- INTS3 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV59676463; called by muse, mutect2, varscan2
- IRS2 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs1025492234, COSV65478325; called by muse, mutect2
- ITPR1 | c.3020C>T p.S1007F (on ENST00000354582; = p.S992F on NM_002222.7) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV56976264; called by muse, mutect2, varscan2
- JARID2 | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV59187644; called by muse, mutect2, varscan2
- KDM6A | c.1544T>C p.V515A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV65038827; called by muse, mutect2, varscan2
- KIAA1549 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1198453491, COSV54310623; called by muse, mutect2, varscan2
- KMT2E | c.4829dup p.L1610Ffs*259 | Frame Shift Ins (INS) | VAF 21/112 reads (19%) | catalogued as rs1243172283; called by mutect2, pindel, varscan2
- KPNA2 | c.1187A>C p.E396A | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57857224; called by muse, mutect2, varscan2
- KRT26 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV59413658; called by muse, mutect2, varscan2
- LAMA4 | c.4747G>A p.E1583K (on ENST00000230538 / NM_001105206.3; = p.E1576K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV57894943; called by muse, mutect2, varscan2
- LAMB4 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52716865; called by muse, mutect2, varscan2
- LGSN | c.1217A>C p.E406A | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65726705; called by muse, mutect2, varscan2
- LOXL4 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV53256023; called by muse, mutect2, varscan2
- LPAR1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.577); catalogued as rs748796192, COSV62688148; called by muse, mutect2, varscan2
- LRRIQ3 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV63041391; called by muse, mutect2
- MAGEA3 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV64755890; called by muse, mutect2, varscan2
- MAGEB3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854860, COSV64396894; called by muse, mutect2
- MAN1A1 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV63782029; called by muse, mutect2, varscan2
- MARCO | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748644550, COSV59053393; called by muse, mutect2, varscan2
- MCCC2 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV60153938; called by muse, mutect2, varscan2
- MDGA1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs368289358, COSV99777151; called by muse, mutect2, varscan2
- MECOM | c.1832G>A p.G611E (on ENST00000468789 / NM_001105078.4; = p.G799E on NM_004991.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599684, COSV52962370; called by muse, varscan2
- MICAL3 | c.4112C>T p.S1371F | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.118); catalogued as rs1003583573, COSV71588221, COSV71588227; called by muse, mutect2
- MRPS15 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as rs370182087; called by muse, mutect2, varscan2
- MTMR4 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV60200029; called by muse, mutect2, varscan2
- MUC16 | c.37721G>A p.R12574K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1434656915, COSV67457404; called by muse, mutect2, varscan2
- MYH2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1389727909, COSV55435196; called by muse, mutect2, varscan2
- MYLK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60608109; called by muse, mutect2, varscan2
- MYLK2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV65658857; called by muse, mutect2, varscan2
- MYOM3 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.529); catalogued as COSV100292471, COSV58396193; called by muse, mutect2
- NAA25 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV55703473, COSV99927519; called by muse, mutect2, varscan2
- NANOG | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs71445169, COSV57551178; called by muse, mutect2
- NEB | c.6217G>A p.G2073R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51079468; called by muse, mutect2, varscan2
- NFATC4 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51599610; called by muse, mutect2, varscan2
- NLRP3 | c.1783A>C p.S595R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as CM097730, COSV60222293; called by muse, mutect2, varscan2
- NOMO1 | c.2324A>T p.Y775F | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.714); catalogued as COSV99814206; called by muse, mutect2
- NOTCH2 | c.6655C>T p.P2219S | Missense Mutation (SNP) | VAF 121/583 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs1386606005, COSV56680938; called by muse, mutect2, varscan2
- NOTCH4 | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV100900597, COSV66679878; called by muse, mutect2, varscan2
- NUMB | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as rs1247709989, COSV61828898; called by muse, mutect2, varscan2
- OBSCN | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.688); catalogued as COSV52760137; called by muse, mutect2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, varscan2
- OR5H6 | c.51G>A p.M17I (on ENST00000642105; = p.M1? on NM_001005479.2) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV67351265; called by muse, mutect2, varscan2
- OR8D1 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV63441981; called by muse, mutect2
- OSBPL7 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV50107825; called by muse, mutect2, varscan2
- PAH | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV61015394; called by muse, mutect2, varscan2
- PCDHB5 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV50649313; called by muse, mutect2, varscan2
- PCDHB6 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs782123595, COSV50693258; called by muse, mutect2, varscan2
- PCDHGA10 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53925481; called by muse, mutect2
- PCYT1B | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV63264569; called by muse, varscan2
- PDGFRA | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57265331; called by muse, mutect2, varscan2
- PDGFRB | c.3292C>T p.R1098W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as rs267600485, COSV53832644; called by muse, mutect2, varscan2
- PENK | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs148519224, COSV59240758; called by muse, mutect2, varscan2
- PEX5 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV56954072; called by muse, mutect2
- PKD1L1 | c.3886G>A p.G1296S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as COSV56962028; called by muse, mutect2, varscan2
- PKHD1L1 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as rs754269006, COSV65740675; called by muse, mutect2, varscan2
- PKHD1L1 | c.8377G>A p.E2793K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs267601719, COSV65736548; called by muse, mutect2, varscan2
- PKP2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs761238380, COSV50728301; called by muse, mutect2
- PLA2R1 | c.4154C>T p.T1385I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51777047; called by muse, mutect2, varscan2
- PLPPR2 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.043); catalogued as rs373918772; called by muse, mutect2
- PLPPR2 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.159); catalogued as COSV99264221; called by muse, mutect2
- POLD1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV70954762; called by muse, mutect2
- PPM1E | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375829; called by muse, mutect2, varscan2
- PPM1E | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375833; called by muse, mutect2, varscan2
- PROX1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54777818; called by muse, mutect2, varscan2
- PRRC2A | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV65685990; called by muse, mutect2, varscan2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 35/219 reads (16%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- PTPN3 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52704663; called by muse, mutect2, varscan2
- RAC1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV61822476; called by muse, mutect2, varscan2
- RAPGEF4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.963); catalogued as COSV51383533; called by muse, mutect2, varscan2
- RBM47 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as rs868711273, COSV55932908; called by muse, mutect2, varscan2
- REPS2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1157451358, COSV58180708; called by muse, mutect2, varscan2
- RNF8 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV57720947; called by muse, mutect2, varscan2
- ROBO1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV71392980; called by muse, mutect2, varscan2
- RPRD2 | c.2951C>T p.P984L | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64819301; called by muse, mutect2, varscan2
- RYR2 | c.11146G>A p.E3716K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63676833; called by muse, mutect2
- SAGE1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs781929129, COSV61012521; called by muse, mutect2, varscan2
- SALL4 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53851322; called by muse, mutect2, varscan2
- SCAMP3 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as COSV56944442; called by muse, mutect2, varscan2
- SCN2A | c.5074G>A p.D1692N | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.858); catalogued as COSV51837528; called by muse, mutect2, varscan2
- SCN3A | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV51806548; called by muse, mutect2, varscan2
- SCP2 | c.396+2T>A p.X132_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV65260851; called by muse, mutect2, varscan2
- SCRN2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV51635426; called by muse, mutect2, varscan2
- SEC14L4 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55399232; called by muse, mutect2, varscan2
- SEC24C | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.138); catalogued as COSV59541122; called by muse, mutect2, varscan2
- SEMA3E | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV57083673; called by muse, mutect2, varscan2
- SH2D4B | c.904A>T p.I302F (on ENST00000646907; = p.I301F on NM_207372.2) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV57894622; called by muse, mutect2, varscan2
- SHOX2 | c.557T>C p.V186A (on ENST00000441443 / NM_006884.3; = p.V210A on NM_003030.4) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV67463426, COSV67463728, COSV67464226; called by muse, mutect2
- SI | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV52271833; called by muse, mutect2, varscan2
- SIPA1L3 | c.4342A>T p.K1448* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV55911796; called by muse, mutect2, varscan2
- SLC28A3 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV66152705; called by muse, mutect2, varscan2
- SLC34A2 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV65941176; called by muse, mutect2
- SLC6A11 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54392031; called by muse, mutect2, varscan2
- SLC9C2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV62944942; called by muse, mutect2
- SMPD3 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV54711411; called by muse, mutect2
- SPEG | c.7618G>A p.E2540K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs776247789, COSV56666449; called by muse, mutect2, varscan2
- SPOCD1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs767250734, COSV57095506; called by muse, mutect2
- STRA6 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV60585464; called by muse, mutect2
- SULF1 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.345); catalogued as COSV52678371; called by muse, mutect2, varscan2
- SV2C | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59217818; called by muse, mutect2, varscan2
- SYNPO2 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100204893; called by muse, mutect2, varscan2
- TAF4B | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52302655; called by muse, mutect2, varscan2
- TAS1R1 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751521830, COSV59839622; called by muse, mutect2, varscan2
- TBC1D8 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs373248214; called by muse, mutect2, varscan2
- TENM1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100950347, COSV64429128; called by muse, mutect2, varscan2
- TLL1 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50270448; called by muse, mutect2
- TMC5 | c.1941C>T p.F647= (on ENST00000396229 / NM_001105248.1; = p.F401= on NM_024780.5) | Splice Region (SNP) | VAF 29/155 reads (19%) | catalogued as rs1468760332, COSV54902842; called by muse, mutect2, varscan2
- TMEM132B | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168610; called by muse, mutect2, varscan2
- TNR | c.2288G>A p.S763N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54878718; called by muse, mutect2, varscan2
- TPTE | c.697G>A p.D233N (on ENST00000618007 / NM_199261.4; = p.D215N on NM_199259.4) | Missense Mutation (SNP) | VAF 26/393 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs753370600; called by muse, mutect2
- TSGA10 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV61822318; called by muse, mutect2, varscan2
- TTN | c.72140A>G p.Q24047R (on ENST00000591111; = p.Q16623R on NM_003319.4) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | PolyPhen benign (0); catalogued as COSV100594761; called by muse, mutect2, varscan2
- TTN | c.71456G>A p.G23819E (on ENST00000591111; = p.G16395E on NM_003319.4) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | PolyPhen probably damaging (1); catalogued as COSV59976745; called by muse, mutect2, varscan2
- TTN | c.10913C>T p.A3638V (on ENST00000591111; = p.A3592V on NM_003319.4) | Missense Mutation (SNP) | VAF 37/170 reads (22%) | catalogued as COSV100594765; called by muse, mutect2, varscan2
- USH2A | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV56352056; called by muse, mutect2, varscan2
- USP17L2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV61555698; called by muse, mutect2
- VASH2 | c.844G>A p.E282K (on ENST00000517399 / NM_001301056.2; = p.E238K on NM_024749.5) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV55116875; called by muse, mutect2, varscan2
- VCAN | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV54102190, COSV54114926; called by muse, mutect2
- VPS13D | c.5276C>T p.P1759L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1480730797, COSV50630979; called by muse, mutect2
- YTHDF3 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV101572355; called by muse, mutect2, varscan2
- ZAN | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs956391790, COSV100769867, COSV61807472; called by muse, mutect2
- ZBED2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs372487455; called by muse, mutect2, varscan2
- ZBTB33 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58533600, COSV58534599; called by muse, mutect2, varscan2
- ZDHHC8 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770122984, COSV57709703; called by muse, mutect2, varscan2
- ZFHX4 | c.7909C>T p.H2637Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV50663203; called by mutect2, varscan2
- ZIM3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.568); catalogued as COSV54141468; called by muse, mutect2, varscan2
- ZNF175 | c.1256A>T p.Y419F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.493); catalogued as COSV51794929; called by muse, mutect2, varscan2
- ZNF229 | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV52161000; called by muse, mutect2, varscan2
- ZNF560 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV56866994; called by muse, varscan2
- ZNF641 | c.416T>G p.M139R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56389937; called by muse, mutect2, varscan2
- ZNF701 | c.1296T>A p.D432E (on ENST00000301093; = p.D366E on NM_018260.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV56524032; called by muse, mutect2, varscan2
- ZNF804A | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV56442852; called by muse, mutect2, varscan2
- ZNF831 | c.4711G>A p.A1571T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV64038953; called by muse, mutect2, varscan2
- DHRS2 | c.455_462del p.L152Pfs*23 | Frame Shift Del (DEL) | VAF 29/159 reads (18%) | called by mutect2, pindel, varscan2
- DIP2C | c.2083_2085del p.K695del | In Frame Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- GPR179 | c.6676G>A p.E2226K (on ENST00000621958; = p.E2225K on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- GPR179 | c.6675G>A p.W2225* (on ENST00000621958; = p.W2224* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TRGV5 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ABCB5 | c.2676G>A p.R892= (on ENST00000404938 / NM_001163941.2; = p.R447= on NM_178559.6) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99327447; called by muse, mutect2, varscan2
- AC008397.2 | c.276G>A p.R92= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV53206234; called by muse, mutect2, varscan2
- ADAMTS16 | c.324C>T p.F108= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs373039727; called by muse, mutect2
- AKR1B10 | c.225C>T p.I75= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs186829500, COSV62055233; called by muse, mutect2, varscan2
- ALG5 | c.171C>T p.P57= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV53504917; called by muse, mutect2, varscan2
- ANK3 | c.4653C>T p.S1551= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV55051761; called by muse, mutect2, varscan2
- ANKRD17 | c.7641C>T p.I2547= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV58218282; called by muse, mutect2, varscan2
- BRD8 | c.918A>G p.Q306= (on ENST00000254900 / NM_139199.2; = p.Q379= on NM_006696.4) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV50146538; called by muse, mutect2, varscan2
- C7 | c.888C>T p.I296= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs757442071, COSV57470913; called by muse, mutect2, varscan2
- CACNA1F | c.5028G>A p.G1676= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV59903886; called by muse, mutect2
- CD1A | c.102C>T p.S34= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs746482126, COSV56861147; called by muse, mutect2, varscan2
- COL4A5 | c.5016G>A p.R1672= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV60359268; called by muse, mutect2
- DNAH10 | c.4761G>A p.V1587= (on ENST00000409039; = p.V1526= on NM_207437.3) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV68990000; called by mutect2, varscan2
- DNAJC14 | c.2034G>A p.K678= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV54478104; called by muse, mutect2, varscan2
- DOCK4 | c.3777C>T p.I1259= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV69854422; called by muse, mutect2, varscan2
- DSG2 | c.582G>A p.S194= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs748768578, COSV55198230; called by muse, mutect2, varscan2
- DUSP22 | c.300C>T p.I100= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs746498411, COSV60524166, COSV60525568, COSV60528378; called by muse, mutect2, varscan2
- ENTHD1 | c.909C>T p.I303= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV57317127, COSV57318865; called by muse, mutect2, varscan2
- EPN3 | c.945C>T p.S315= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV52139040; called by muse, mutect2
- EWSR1 | c.1506C>T p.P502= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs763253549, COSV58422784; called by muse, mutect2, varscan2
- FAM83D | c.1653G>A p.R551= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV99464972; called by muse, mutect2, varscan2
- FBXO31 | c.1608C>T p.S536= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV61148275; called by muse, mutect2, varscan2
- FPR3 | c.93A>G p.L31= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59328957; called by muse, mutect2, varscan2
- FREM2 | c.5520G>A p.R1840= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV54833975; called by muse, mutect2
- FRMPD3 | c.426G>A p.A142= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs750213017, COSV52193110; called by muse, mutect2, varscan2
- GABRB2 | c.951C>T p.F317= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV50906470; called by muse, mutect2
- GIMAP7 | c.837G>A p.R279= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1563302629, COSV57958896; called by muse, mutect2, varscan2
- GIMAP8 | c.1365G>T p.G455= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV56230752; called by muse, mutect2, varscan2
- GJB2 | c.24G>A p.T8= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs533231493, CM137451, COSV67010644; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GRHL2 | c.981G>A p.A327= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs368774126; ClinVar: benign; called by muse, mutect2, varscan2
- GRIA1 | c.2577C>T p.L859= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99598204; called by muse, mutect2
- GRK3 | c.1269C>T p.S423= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV60794965; called by muse, mutect2, varscan2
- GSPT2 | c.1725C>T p.F575= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV61213999; called by muse, mutect2, varscan2
- HDAC4 | c.3048C>T p.S1016= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV61862854; called by muse, mutect2, varscan2
- IGSF1 | c.2526T>G p.G842= | Silent (SNP) | VAF 39/299 reads (13%) | catalogued as COSV63836872; called by muse, mutect2, varscan2
- IL2RG | c.915G>A p.G305= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV52147458, COSV99340476; called by muse, mutect2
- JUP | c.1026C>T p.P342= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs1212678389, COSV60277568; called by muse, mutect2, varscan2
- KCNH4 | c.834C>T p.I278= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV52916469; called by muse, mutect2
- KRTAP3-2 | c.54C>T p.T18= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs752143236, COSV66957027; called by muse, mutect2, varscan2
- LONP1 | c.1225C>T p.L409= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs761401147, COSV62261219; called by muse, mutect2, varscan2
- MEF2D | c.1446C>T p.D482= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV61727581; called by muse, mutect2, varscan2
- MFSD4A | c.891G>A p.R297= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV65656305; called by muse, mutect2, varscan2
- MOG | c.48C>T p.F16= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV65320944; called by muse, mutect2
- MPP7 | c.879C>T p.F293= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV61731246; called by muse, mutect2, varscan2
- MTMR4 | c.2106C>T p.Y702= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as COSV60200020; called by muse, mutect2, varscan2
- MTMR7 | c.630C>T p.S210= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs370841686, COSV51664571; called by muse, mutect2, varscan2
- MYH9 | c.2496C>T p.T832= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs769382495, COSV53384286; called by muse, mutect2, varscan2
- MYLK | c.2466G>A p.G822= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1253095533, COSV60608103; called by muse, mutect2
- MYMK | c.196C>T p.L66= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV60600349; called by muse, mutect2
- NBEA | c.7713C>T p.F2571= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as COSV59773205; called by muse, mutect2, varscan2
- NCKAP1L | c.2400G>A p.Q800= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as COSV53205407; called by muse, mutect2, varscan2
- NIBAN1 | c.1320G>A p.Q440= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV62284170; called by muse, mutect2, varscan2
- NKAIN3 | c.432C>T p.Y144= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs749315836, COSV60655626; called by muse, mutect2, varscan2
- NPHS1 | c.2970C>T p.V990= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs778497725, COSV62286477; called by muse, mutect2, varscan2
- OBSCN | c.4842C>T p.S1614= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV52760165; called by muse, mutect2
- OR13C2 | c.771C>T p.F257= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV73377680; called by muse, mutect2, varscan2
- OR2K2 | c.768C>T p.I256= (on ENST00000374428; = p.I227= on NM_205859.2) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs923046534, COSV100235110; called by muse, varscan2
- OR4K17 | c.678G>A p.K226= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV59647746; called by muse, mutect2, varscan2
- ORM1 | c.303G>A p.R101= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV52279016; called by muse, mutect2, varscan2
- PBXIP1 | c.966C>T p.A322= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV63776982; called by muse, mutect2
- PCDHGB1 | c.1599G>A p.Q533= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV53925462; called by muse, mutect2, varscan2
- PCK1 | c.633C>T p.P211= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV60127197, COSV60128711; called by muse, mutect2
- PCNX1 | c.6588C>T p.S2196= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV53092449; called by muse, mutect2, varscan2
- PKD1L1 | c.6033C>T p.S2011= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs759955149, COSV56962019; called by muse, mutect2, varscan2
- PLCB1 | c.3309C>T p.I1103= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs768348192, COSV62045380; called by muse, mutect2, varscan2
- PNMA8B | c.1203C>T p.V401= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV66536263; called by muse, mutect2
- RASAL1 | c.874T>C p.L292= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV55655063; called by muse, varscan2
- RFPL1 | c.420T>A p.I140= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV62977654; called by muse, mutect2, varscan2
- RGL4 | c.681G>A p.L227= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV51943546; called by muse, mutect2, varscan2
- RNF157 | c.411G>A p.Q137= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV53943159; called by muse, mutect2
- RPS6KA1 | c.1197C>T p.P399= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV65175873; called by muse, mutect2, varscan2
- SALL4 | c.1209C>T p.S403= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99409191; called by muse, mutect2, varscan2
- SMG5 | c.1371C>T p.S457= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV62434764; called by muse, mutect2, varscan2
- SORBS2 | c.1032C>T p.V344= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV52996103; called by muse, mutect2, varscan2
- SORCS3 | c.1977G>A p.L659= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100863397; called by muse, mutect2, varscan2
- SPANXN5 | c.171G>A p.R57= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV64968712; called by muse, mutect2
- SPOCD1 | c.2019C>T p.P673= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV57095494; called by muse, mutect2, varscan2
- ST7L | c.1054C>T p.L352= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV58308099; called by muse, mutect2, varscan2
- SUN5 | c.372G>A p.S124= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs757677259, COSV62180652; called by muse, mutect2, varscan2
- SYNJ2 | c.3363G>A p.K1121= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs1417614509, COSV62896574; called by muse, mutect2, varscan2
- SYNPO2 | c.606C>T p.S202= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1303148129, COSV100204896; called by muse, mutect2, varscan2
- TAS2R31 | c.30C>T p.S10= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1461191173, COSV66830076; called by muse, mutect2, varscan2
- TBCE | c.216G>A p.P72= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs777273223, COSV64005774, COSV64006779; called by muse, mutect2, varscan2
- TCEAL3 | c.591C>T p.I197= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV54580396; called by muse, mutect2, varscan2
- TET1 | c.2844A>T p.G948= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV65383621; called by muse, mutect2, varscan2
- TMEM132B | c.2619C>A p.P873= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV54749994, COSV54760184; called by muse, mutect2, varscan2
- TNXB | c.6069C>T p.P2023= (on ENST00000647633; = p.P1776= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/416 reads (18%) | catalogued as COSV64476799; called by muse, mutect2, varscan2
- TOGARAM2 | c.2157C>T p.P719= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs761837091, COSV101090955, COSV65420727; called by muse, mutect2
- TOMM40 | c.969C>T p.I323= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV52985301; called by muse, mutect2, varscan2
- TSPYL6 | c.174G>A p.G58= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as rs1294411786, COSV57813619; called by muse, mutect2
- TTN | c.64314G>A p.K21438= (on ENST00000591111; = p.K14014= on NM_003319.4) | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV59976780; called by muse, mutect2, varscan2
- ZFHX4 | c.8610C>T p.S2870= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV50663370; called by muse, mutect2, varscan2
- DCHS2 | n.6844C>T | RNA (SNP) | VAF 8/46 reads (17%) | catalogued as rs559445336, COSV61769993, COSV61781989; called by muse, mutect2, varscan2
- DCHS2 | n.3204C>T | RNA (SNP) | VAF 21/98 reads (21%) | catalogued as rs762099114, COSV59722739; called by muse, mutect2, varscan2
- FOLH1B | n.1551G>A | RNA (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- MIR526B | n.46G>A | RNA (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- OR2W5 | n.650T>C | RNA (SNP) | VAF 11/77 reads (14%) | catalogued as rs764270540; called by muse, mutect2, varscan2
- RPS6KA1 | c.109-890G>A | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100837895; called by muse, mutect2
- SNORD115-10 | n.65G>A | RNA (SNP) | VAF 69/252 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.10360+1614G>A | Intron (SNP) | VAF 22/119 reads (18%) | catalogued as rs749558211, COSV100594766; called by muse, mutect2, varscan2
